Gene-level copy-number profile of specimen HCM-CSHL-0078-C25-85B from HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 40228b1f-268c-44a8-abcd-93c7dc1de357.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0078-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,870 have no estimate.
https://portal.gdc.cancer.gov/files/871e86fe-bd27-4321-a6ea-60fb9e41b789

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 328; copy number 1: 3,051; copy number 2: 24,290; copy number 3: 24,733; copy number 4: 4,627; copy number 5: 58; copy number 6: 665; copy number 7: 261; copy number 8: 377; copy number 9: 11; copy number 10: 199; copy number 11: 7; copy number 12: 49; copy number 14: 16; copy number 15: 11; copy number 16: 11; copy number 17: 46; copy number 23: 13.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,001 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,078,062–84,238,498, 1 gene, copy number 7 (within-gene range 2–7): PRKACB.
- chr1:84,244,334–84,397,831, 5 genes, copy number 7: NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX.
- chr1:87,620,803–88,685,204, 1 gene, copy number 9 (within-gene range 3–9): PKN2-AS1.
- chr1:88,313,153–88,578,201, 5 genes, copy number 9: AL049861.1, RN7SL583P, AC093578.1, AC093578.2, RPL36AP10.
- chr1:143,419,625–145,918,717, 84 genes, copy number 14–17 (broad region; genes not listed).
- chr1:150,560,202–152,196,699, 97 genes, copy number 7–12 (within-gene range 6–12) (broad region; genes not listed).
- chr1:157,573,747–158,203,877, 19 genes, copy number 8: FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1.
- chr1:158,289,923–158,331,531, 2 genes, copy number 7: CD1C, CD1B.
- chr1:159,535,078–162,039,567, 127 genes, copy number 7–9 (broad region; genes not listed).
- chr1:163,923,670–164,357,364, 4 genes, copy number 8: U3, NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:165,400,922–169,104,907, 95 genes, copy number 7–10 (broad region; genes not listed).
- chr6:25,726,063–28,633,594, 173 genes, copy number 8 (broad region; genes not listed).
- chr6:29,657,002–29,995,314, 38 genes, copy number 8: MOG, ZFP57, ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1, MICE, AL645939.2, Y_RNA, IFITM4P, AL645939.4, AL645939.5, AL645939.3, HLA-V, HCG4, HLA-P, RPL7AP7, MICG, HLA-G, HCG4P8, AL645929.2, HCP5B, AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1, HLA-W, MICD, HCG9, DDX39BP2, MCCD1P2.
- chr6:30,005,971–30,009,956, 2 genes, copy number 8 (within-gene range 3–8): HLA-J, AL671277.2.
- chr6:32,439,878–33,457,544, 74 genes, copy number 7–23 (broad region; genes not listed).
- chr6:41,247,369–53,924,125, 274 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 523. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
